Somatic mutation profile of tumor specimen 0DMIOJ from CCDI case PBBZDY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Myxopapillary ependymoma; Tissue or organ of origin: Spinal cord; Age at diagnosis: 21.7 years (7,939 days).
Specimen 0DMIOJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 89d09207-200a-4b13-80f4-31217fe7713a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMIPG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3561dced-816b-49e6-b99b-a34cf9ed898e

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NSD2 | c.4076G>A p.R1359Q | Missense Mutation (SNP) | VAF 125/430 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.042); catalogued as rs1560827075; called by muse, varscan2
- ZP1 | c.682G>T p.G228C | Missense Mutation (SNP) | VAF 91/342 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53926554; called by muse, varscan2
- H4C1 | c.40G>A p.G14R | Missense Mutation (SNP) | VAF 168/670 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, varscan2
- WNK2 | c.2536C>T p.P846S | Missense Mutation (SNP) | VAF 87/541 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.03); called by muse, varscan2
- MAGEC3 | c.1124-34C>T | Intron (SNP) | VAF 206/888 reads (23%) | called by muse, varscan2
- RUBCN | c.2646+43T>C | Intron (SNP) | VAF 92/356 reads (26%) | called by muse, varscan2
- SLC35B4 | c.673+13T>C | Intron (SNP) | VAF 242/628 reads (39%) | called by muse, varscan2
